Surgical pathology report (de-identified scan), CDDP_EAGLE case CDDP-ACLV, project CDDP_EAGLE-1 (CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2)), specimen CDDP-ACLV-TTP1-A (Primary Tumor).

[page 1 of 2]
ACINAR ADENOCARCINOMA, POORLY DIFFERENTIATED

Sent Material

- A) Right upper lung lobe, removal
- B) pre and retrotracheal lymph nodes, removal
- C) paratracheal lower lymph nodes, removal
- D) subcarinal lymph nodes removal
- E) lung ligament lymph node, removal
- F) hilar lymph node, removal

CDDP-YP-ACLV-01-PR

Macroscopic report:

A) Lung lobe of 14 x 11 x 4 cm, closed by metal stitches on the hilum side of 7 cm stretch of length, with focally retracted and opacata pleura.
To cut, in place intraparenchymal, there is a lesion of 5,5 cm of major axis, white – blackish, with polycyclic margins, gradient, which is 2,7 cm from the bronchial resection margin and 0.6 cm from the pleural surface. The remaining parenchyma does not show significant alterations.
By peribronchial tissue isolate 7 lymph nodes.
Intraoperative examination performed on the of bronchial and vascular resection margin.

(A1 definitive intraoperative examination; A2 bronchial and vascular resection margin; A3 neoplasm via the bronchial; A4 pleural neoplasm; A5 adjacent lung parenchymal cancer; A6 opacata and retracted pleura; A7 distal parenchyma; A8-A10 lymph nodes (A10a lymph node)

- B) Five yellowish brown fragments of long axis between 0,5 cm and 1,1 cm.
- C) One lymph node of 1,3 the major axis.
- D) Four blackish fragments, the major axis between 0,6 cm and 0,3 cm.
- E) One lymph node of 0,7 cm the major axis.
- F) One lymph node of 0,5 cm the major axis.

Histopathological diagnosis

A-E) adenocarcinoma lung poorly differentiated acinar type angiotropo extensively necrotic .
District of fibrosis area parenchymal sub pleural associated with chronic inflammation.
Visceral pleura, bronchial and vascular resection margins free of neoplasia. Free of metastases
all the lymph nodes in question, the site of anthracosis and sinus histiocytosis .
F) lung parenchyma site of irregular fibrosis and anthracosis, free from neoplasia did not reveal
any lymph node parenchyma in the sample. Intraoperative diagnosis of A : negative
broncho vascular resection margin for neoplasia .

Histopathologic staging: pT2N0

Codes SNOMED

T-28200 M-81403 M-43000

T-C4270 M-43000

T-C4340 M-43000

ICD-0-3

adenocarcinoma, acinar 8550/3
Site: (R) lung, upper lobe C34.1

ICD-10

C34.11

hw
12/16/16

[page 2 of 2]
T-C4000 M-43000
T-C4310 M-43000
T-C4610 M-43000
T-28200 M-00100F-C001

CYTOLOGY

SENT MATERIAL

- A)BRONCO ASPIRATED
- B)BRONCHIAL BRUSHING

DIAGNOSI

A-B) positive for malignant tumor cells, oncotipo likely adenocarcinoma

HPV/AA Discrepancy		/

Source: NCI Genomic Data Commons file dfd7ebfa-cb9c-4c69-8af5-71dde303a763 (CDDP-ACLV-TTP1.6511AC7D-5E5F-4726-9CA6-59766B4823D9.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).